Somatic mutation profile of tumor specimen BA2974D (aliquot aq-BA2974D) from BEATAML1.0 case 2435, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.2 years (25,264 days).
Specimen BA2974D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb65ba21-0bdb-47af-bf6b-1046d486af9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3012D (Solid Tissue Normal), aliquot aq-BA3012D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e08f8ab-709c-404f-a0c4-b74c8a253118

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Intron 2, Splice Site 1, In Frame Del 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AATK | c.1478C>T p.T493M (on ENST00000326724 / NM_001080395.3; = p.T390M on NM_004920.2) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV58692122; called by muse, varscan2
- CGN | c.187C>A p.Q63K | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs985514918; called by muse, mutect2
- ZNF275 | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.76); PolyPhen benign (0.259); catalogued as rs782626018, COSV64705253; called by muse, mutect2, varscan2
- CEBPA | c.937_939del p.K313del | In Frame Del (DEL) | VAF 108/334 reads (32%) | called by mutect2, varscan2
- DPF2 | c.904+2T>C p.X302_splice | Splice Site (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- EDC4 | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- GPR108 | c.724G>T p.V242L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2
- MTMR8 | c.1488G>A p.W496* | Nonsense Mutation (SNP) | VAF 10/15 reads (67%) | called by muse, mutect2, varscan2
- MUC3A | c.116C>A p.A39E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- MYO7A | c.826T>C p.S276P | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2
- PTPN1 | c.767_768insGCC p.F256delinsLP | In Frame Ins (INS) | VAF 12/147 reads (8%) | called by mutect2, pindel
- SETD5 | c.2130C>A p.D710E | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.991); called by muse, mutect2
- SLC4A2 | c.1697A>G p.N566S | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ERBB2 | c.1881C>A p.P627= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- MDH1B | c.30A>G p.A10= | Silent (SNP) | VAF 31/109 reads (28%) | called by muse, mutect2, varscan2
- ZFHX4 | c.2214G>A p.V738= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as rs776731360; called by muse, mutect2, varscan2
- CTDSPL | c.426+1565A>G | Intron (SNP) | VAF 8/13 reads (62%) | catalogued as rs190898565; called by muse, varscan2
- LAMB2 | c.1890+32C>T | Intron (SNP) | VAF 20/82 reads (24%) | called by muse, mutect2, varscan2
